Somatic mutation profile of tumor specimen C3N-01413-01 (aliquot CPT0105510009) from CPTAC case C3N-01413, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 62.2 years (22,704 days).
Specimen C3N-01413-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6ac7dba-0faf-4c96-85f6-2d398be42cab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01413-31 (Blood Derived Normal), aliquot CPT0107980002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da47c336-a6d8-49c7-902f-35eb137db339

The open-access MAF lists 62 somatic variants for this specimen: 38 protein-altering or splice-affecting, 16 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 16, Intron 4, 3'UTR 2, Nonsense Mutation 2, Nonstop Mutation 1, In Frame Del 1, Frame Shift Ins 1, Splice Region 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 120/450 reads (27%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.568C>A p.P190T | Missense Mutation (SNP) | VAF 49/433 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as rs876660254, COSV52672087, COSV52843475, COSV52949919; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC3 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs375273144; called by muse, mutect2
- ALDH3A1 | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 47/378 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs368399148; called by muse, mutect2, varscan2
- AXIN1 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 23/539 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as rs1366873157; called by muse, mutect2
- CWH43 | c.1220G>T p.G407V | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV99893262; called by muse, mutect2
- GPR101 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 17/516 reads (3%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV53237573; called by muse, mutect2
- MGA | c.7592A>C p.K2531T (on ENST00000219905 / NM_001164273.1; = p.K2322T on NM_001080541.2) | Missense Mutation (SNP) | VAF 43/315 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV99582383; called by muse, mutect2, varscan2
- PANX3 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV52513691, COSV52514334; called by muse, mutect2
- PCDHA2 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 38/768 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs202116317; called by muse, mutect2
- PRPS2 | c.9C>A p.N3K | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as COSV66126386; called by muse, mutect2
- SYNPO | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 20/507 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239717910, COSV56939368; called by muse, mutect2
- TAX1BP1 | c.122A>G p.Y41C | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.967); catalogued as rs758522444; called by muse, mutect2, varscan2
- TMEM132D | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 21/273 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.178); catalogued as COSV101397331; called by muse, mutect2
- TNFRSF21 | c.143C>A p.S48* | Nonsense Mutation (SNP) | VAF 16/101 reads (16%) | catalogued as COSV57285310; called by muse, mutect2, varscan2
- ASB17 | c.503A>T p.Q168L | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.901); called by muse, mutect2
- ATP6AP1 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 38/299 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ATR | c.2132T>G p.L711R | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2
- CHRNG | c.581T>A p.F194Y | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.588); called by muse, mutect2
- CYP2C8 | c.1265G>A p.S422N | Missense Mutation (SNP) | VAF 37/294 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- DSCAM | c.5860G>A p.A1954T | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- DST | c.12253C>T p.Q4085* (on ENST00000361203 / NM_001374722.1; = p.Q1673* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 39/489 reads (8%) | called by muse, mutect2
- ITIH1 | c.1364C>T p.A455V | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- KANSL3 | c.323T>C p.I108T | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.071); called by muse, mutect2
- MAFK | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 12/267 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MARCHF7 | c.1970T>C p.M657T | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- MAST2 | c.1793C>T p.A598V | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MTIF2 | c.2182T>C p.*728Qext*? | Nonstop Mutation (SNP) | VAF 7/72 reads (10%) | called by muse, varscan2
- MYO5C | c.3401A>T p.D1134V | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.275); called by muse, mutect2
- NEB | c.15107C>T p.P5036L | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2
- NPY1R | c.428T>G p.I143S | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2
- SEPTIN4 | c.583T>A p.S195T | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2
- SLC2A14 | c.90C>A p.V30= | Splice Region (SNP) | VAF 28/186 reads (15%) | called by muse, mutect2, varscan2
- SLMAP | c.781G>C p.V261L | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TACC2 | c.5716dup p.A1906Gfs*22 | Frame Shift Ins (INS) | VAF 26/156 reads (17%) | called by mutect2, pindel, varscan2
- UCP2 | c.149C>G p.P50R | Missense Mutation (SNP) | VAF 17/273 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2
- ZC3H12A | c.1495C>G p.P499A | Missense Mutation (SNP) | VAF 17/302 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.117); called by muse, mutect2
- ZNF8 | c.1247A>T p.Q416L | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- ABHD3 | c.1215A>G p.G405= | Silent (SNP) | VAF 10/236 reads (4%) | catalogued as rs1414217873; called by muse, mutect2
- CNKSR2 | c.330C>G p.G110= | Silent (SNP) | VAF 14/304 reads (5%) | called by muse, mutect2
- CYP27A1 | c.1113C>T p.A371= | Silent (SNP) | VAF 26/410 reads (6%) | catalogued as rs746269951; called by muse, mutect2
- FCRLB | c.1168C>T p.L390= | Silent (SNP) | VAF 78/279 reads (28%) | called by muse, mutect2, varscan2
- GPR139 | c.897G>A p.T299= | Silent (SNP) | VAF 29/405 reads (7%) | catalogued as rs758294318, COSV100429827, COSV58503668; called by muse, mutect2
- KIF24 | c.693C>T p.R231= | Silent (SNP) | VAF 14/137 reads (10%) | called by muse, mutect2, varscan2
- LOXHD1 | c.4152C>T p.G1384= | Silent (SNP) | VAF 39/311 reads (13%) | catalogued as rs758494024; called by muse, mutect2, varscan2
- MAPK4 | c.672G>A p.T224= | Silent (SNP) | VAF 14/135 reads (10%) | catalogued as rs550266883, COSV68541070; called by muse, mutect2, varscan2
- MC1R | c.168C>T p.N56= | Silent (SNP) | VAF 18/292 reads (6%) | catalogued as rs373707533; called by muse, mutect2
- NWD2 | c.1884C>T p.D628= | Silent (SNP) | VAF 36/388 reads (9%) | catalogued as rs562713907; called by muse, mutect2
- RBBP8 | c.174A>G p.E58= | Silent (SNP) | VAF 34/263 reads (13%) | called by muse, mutect2, varscan2
- RBMXL3 | c.2682C>T p.R894= | Silent (SNP) | VAF 19/308 reads (6%) | catalogued as rs782270933; called by muse, mutect2
- SHMT1 | c.138T>A p.V46= | Silent (SNP) | VAF 65/459 reads (14%) | called by muse, mutect2, varscan2
- SLC1A3 | c.1365G>T p.L455= | Silent (SNP) | VAF 27/462 reads (6%) | called by muse, mutect2
- SMARCA2 | c.894C>T p.P298= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- ZNF362 | c.1131G>C p.G377= | Silent (SNP) | VAF 24/162 reads (15%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-9310C>T | Intron (SNP) | VAF 23/649 reads (4%) | catalogued as COSV73145147; called by muse, mutect2
- ARHGAP23P1 | chr16:33938526 C>T | 5'Flank (SNP) | VAF 19/204 reads (9%) | catalogued as rs781641219; called by muse, mutect2, varscan2
- CDH4 | c.170-24492G>T | Intron (SNP) | VAF 15/306 reads (5%) | called by muse, mutect2
- RASA1 | c.539+65G>A | Intron (SNP) | VAF 18/398 reads (5%) | called by muse, mutect2
- SLC35A2 | c.1163+160T>A | Intron (SNP) | VAF 11/223 reads (5%) | called by muse, mutect2
- TMCO1 | c.*746A>T | 3'UTR (SNP) | VAF 16/212 reads (8%) | called by muse, mutect2
- TMEM135 | c.*6954T>C | 3'UTR (SNP) | VAF 12/254 reads (5%) | called by muse, mutect2
- WDR72 | c.-6C>T | 5'UTR (SNP) | VAF 14/293 reads (5%) | catalogued as rs1391484109; called by muse, mutect2
